TCGA case TCGA-06-0188 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6573378a-ad14-4654-8810-9f3bd3597bc2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 1,356 days (3.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 71.4 years (26,080 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 68 days; Treatment dose: 6,000 cGy; Course number: 1; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 68 days; Number of cycles: 1; Treatment dose: 140 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 300 days; Number of cycles: 8; Treatment dose: 380 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 334 days; Days to treatment end: 949 days (2.6 years); Number of cycles: 22; Treatment dose: 75 mg/day; Prescribed dose: 75; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Initial disease status: Progressive Disease; Days to treatment start: 334 days; Days to treatment end: 949 days (2.6 years); Number of cycles: 22; Treatment dose: 200 mg/day; Prescribed dose: 200; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 965 days (2.6 years); Days to treatment end: 1,342 days (3.7 years); Number of cycles: 12; Treatment dose: 864 mg; Prescribed dose: 10; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 965 days (2.6 years); Days to treatment end: 1,230 days (3.4 years); Number of cycles: 8; Treatment dose: 254 mg; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,244 days (3.4 years); Days to treatment end: 1,337 days (3.7 years); Number of cycles: 2; Treatment dose: 150 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,342 days (3.7 years); Days to treatment end: 1,342 days (3.7 years); Number of cycles: 1; Treatment dose: 50 mg; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.3 years (26,390 days); Days to diagnosis: 310 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 310 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 866 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,356 days (3.7 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0188-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0188-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-06-0188-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30.
- Sample TCGA-06-0188-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0188-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 01.
- Drug treatment 3: Regimen number: 02; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 05; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 03; Therapy regimen: Progression.
- Drug treatment 6, Route of administrations: Route of administration: IV.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 2, New tumor event: New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,356 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,356 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 310 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-0188-01A-01D-0236-01): tumor purity 0.82, ploidy 1.91, whole-genome doublings 0.
